Somatic mutation profile of tumor specimen ALCH-B1MY-TTP1-A (aliquot ALCH-B1MY-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1MY, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.6 years (25,063 days).
Specimen ALCH-B1MY-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b156c6f-be83-4700-8e8e-d7c5cb7f8f21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1MY-NB1-A (Blood Derived Normal), aliquot ALCH-B1MY-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76988186-a6e6-4935-9e21-196130b1f50f

The open-access MAF lists 208 somatic variants for this specimen: 134 protein-altering or splice-affecting, 45 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 45, Intron 19, Nonsense Mutation 10, Frame Shift Del 8, 3'UTR 4, 3'Flank 2, Frame Shift Ins 2, Splice Site 2, RNA 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.993+1G>T p.X331_splice | Splice Site (SNP) | VAF 23/134 reads (17%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: not provided / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993G>T p.Q331H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as rs11575996, CS125161, COSV52681350, COSV52690011, COSV52951377, COSV99391417; called by muse, mutect2, varscan2
- APBA1 | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.749); catalogued as COSV55232069; called by muse, mutect2, varscan2
- ARSJ | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59537717; called by muse, mutect2, varscan2
- C9orf131 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV56610485, COSV56611388; called by muse, mutect2, varscan2
- CCDC86 | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.203); catalogued as COSV57126504; called by muse, mutect2, varscan2
- CD300A | c.126C>A p.H42Q | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs372925371; called by muse, mutect2, varscan2
- CHD9 | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.253); catalogued as rs772196014; called by muse, mutect2
- CNTN1 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 103/328 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61645096; called by muse, mutect2, varscan2
- CNTN6 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV63167869; called by muse, mutect2, varscan2
- COL3A1 | c.2561C>A p.P854H | Missense Mutation (SNP) | VAF 111/406 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.628); catalogued as COSV58586283; called by muse, mutect2, varscan2
- DACH2 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 71/124 reads (57%) | catalogued as COSV64178420; called by muse, mutect2, varscan2
- DSG4 | c.2570C>A p.S857* | Nonsense Mutation (SNP) | VAF 48/206 reads (23%) | catalogued as COSV57392612; called by muse, mutect2, varscan2
- GP2 | c.1207G>T p.A403S (on ENST00000381362 / NM_001007240.3; = p.A400S on NM_001502.4) | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56892206; called by muse, mutect2, varscan2
- GYPA | c.158A>C p.Y53S | Missense Mutation (SNP) | VAF 120/373 reads (32%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.936); catalogued as COSV51619421; called by muse, mutect2, varscan2
- H2BW2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54584668; called by muse, mutect2, varscan2
- KCNJ3 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.007); catalogued as COSV54539650; called by muse, mutect2, varscan2
- KCNT2 | c.739del p.D247Mfs*13 | Frame Shift Del (DEL) | VAF 105/297 reads (35%) | catalogued as COSV54111833; called by mutect2, pindel, varscan2
- KIAA1109 | c.1357C>T p.L453F | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as COSV99169557; called by muse, mutect2, varscan2
- KLHL28 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); catalogued as COSV61889086; called by muse, mutect2, varscan2
- LCT | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 54/188 reads (29%) | SIFT tolerated (0.81); PolyPhen benign (0.077); catalogued as rs1170254481; called by muse, mutect2, varscan2
- LPP | c.873del p.N292Tfs*105 | Frame Shift Del (DEL) | VAF 100/637 reads (16%) | catalogued as rs1372276132; called by mutect2, pindel, varscan2
- LRRTM1 | c.947G>T p.W316L | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54448024; called by muse, mutect2, varscan2
- MRGPRF | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV57996476; called by muse, mutect2, varscan2
- MRPL55 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV54342242; called by muse, mutect2, varscan2
- MYL1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV58976641; called by muse, mutect2, varscan2
- OR11H1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 96/791 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as rs762582645, COSV53272075; called by muse, varscan2
- OR1C1 | c.646G>T p.V216L | Missense Mutation (SNP) | VAF 133/308 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs770848084, COSV68715741; called by muse, mutect2, varscan2
- OR1S1 | c.814T>C p.Y272H | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565108863; called by muse, mutect2, varscan2
- OR2G2 | c.770C>A p.T257N | Missense Mutation (SNP) | VAF 122/268 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.959); catalogued as COSV60741047; called by muse, mutect2, varscan2
- OR4X2 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1159320108, COSV99043428; called by muse, mutect2, varscan2
- OR5D13 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV100686791; called by muse, mutect2, varscan2
- PHLPP2 | c.2175G>T p.L725F | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.34); catalogued as rs199619105; called by muse, mutect2, varscan2
- RNF130 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 134/511 reads (26%) | catalogued as rs368728115, COSV56148457; called by muse, mutect2, varscan2
- SMARCA4 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 87/313 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV60789139; called by muse, mutect2, varscan2
- SYBU | c.634C>A p.Q212K (on ENST00000276646 / NM_001099754.2; = p.Q211K on NM_017786.6) | Missense Mutation (SNP) | VAF 109/398 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs979818783; called by muse, mutect2, varscan2
- SYT3 | c.1502C>G p.A501G | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100144380; called by muse, mutect2, varscan2
- TEX15 | c.3730A>G p.I1244V (on ENST00000256246; = p.I1627V on NM_001350162.2) | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs1464510010; called by muse, mutect2, varscan2
- TGM7 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746158461, COSV71772887; called by muse, mutect2, varscan2
- TMEM74B | c.476T>C p.M159T | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs755191490; called by muse, mutect2, varscan2
- TNFRSF1A | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV50599069; called by muse, mutect2, varscan2
- TNR | c.1162G>A p.G388S | Missense Mutation (SNP) | VAF 82/443 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs779382990; called by muse, mutect2, varscan2
- TRIM35 | c.443G>A p.C148Y | Missense Mutation (SNP) | VAF 79/276 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs565181133; called by muse, mutect2, varscan2
- TTC38 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs896111969, COSV101123898, COSV66843927; called by muse, mutect2
- USP25 | c.527A>G p.N176S | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1257328910; called by muse, mutect2, varscan2
- VAT1 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as rs1260772343; called by muse, mutect2, varscan2
- WDR86 | c.303C>T p.N101= | Splice Region (SNP) | VAF 29/93 reads (31%) | catalogued as COSV57840502; called by mutect2, varscan2
- ZFPM2 | c.3163G>T p.A1055S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV65873996; called by muse, mutect2, varscan2
- ZNF479 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 65/328 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV58637238, COSV58641252; called by muse, mutect2, varscan2
- AC100868.1 | c.1588dup p.R530Pfs*7 | Frame Shift Ins (INS) | VAF 79/377 reads (21%) | called by mutect2, pindel, varscan2
- ALDH3A1 | c.296_297insGCTCTG p.Y99delins* | Nonsense Mutation (INS) | VAF 9/192 reads (5%) | called by mutect2, varscan2*
- ALLC | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ANKS1B | c.1962A>C p.E654D | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ARID1A | c.1042del p.A348Pfs*15 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- ASPM | c.8233A>G p.I2745V | Missense Mutation (SNP) | VAF 51/277 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- ATCAY | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- ATP1A2 | c.802A>G p.I268V | Missense Mutation (SNP) | VAF 153/322 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BICRAL | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 131/335 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD8 | c.3068C>A p.S1023* | Nonsense Mutation (SNP) | VAF 61/227 reads (27%) | called by muse, mutect2, varscan2
- BVES | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 63/159 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- C15orf39 | c.2801_2804del p.A934Gfs*16 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- C1QL4 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- C2orf16 | c.4187C>A p.A1396D | Missense Mutation (SNP) | VAF 213/414 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CACNA1H | c.4469T>A p.L1490Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CACNA1S | c.1409T>A p.V470E | Missense Mutation (SNP) | VAF 207/468 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CALCR | c.935A>G p.H312R (on ENST00000649521 / NM_001164737.2; = p.H296R on NM_001742.4) | Missense Mutation (SNP) | VAF 103/392 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- CASZ1 | c.3338C>T p.T1113I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CCDC107 | c.737G>C p.G246A | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC112 | c.1150C>A p.Q384K | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- CCDC141 | c.3761G>A p.G1254E | Missense Mutation (SNP) | VAF 91/366 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CCDC186 | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.02); called by muse, varscan2
- CCDC186 | c.106A>T p.S36C | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, varscan2
- CDC16 | c.1213A>T p.M405L | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDKN2A | c.47_60del p.L16Rfs*23 | Frame Shift Del (DEL) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- CPNE4 | c.868A>G p.I290V | Missense Mutation (SNP) | VAF 56/308 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CSHL1 | c.376A>T p.S126C (on ENST00000309894 / NM_022581.3; = p.S32C on NM_001318.4) | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CSMD1 | c.9392C>A p.S3131Y (on ENST00000520002; = p.S3130Y on NM_033225.6) | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD3 | c.5243G>A p.R1748K (on ENST00000297405 / NM_001363185.1; = p.R1644K on NM_052900.3) | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CTNNA3 | c.2324A>T p.Y775F | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ETHE1 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 106/273 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- FAM47B | c.201T>A p.D67E | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FCRL2 | c.1434G>T p.W478C | Missense Mutation (SNP) | VAF 163/375 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FGF14 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.286); called by muse, varscan2
- FSTL5 | c.2379G>T p.W793C | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GANC | c.2587G>C p.V863L | Missense Mutation (SNP) | VAF 75/301 reads (25%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR141 | c.438_440del p.I146_V147delinsM | In Frame Del (DEL) | VAF 42/166 reads (25%) | called by mutect2, pindel, varscan2
- IGKV2D-26 | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- IL12A | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 126/252 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- IRAG1 | c.1912C>A p.Q638K | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IRX2 | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ITIH2 | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 117/361 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ITPRID1 | c.394del p.S132Afs*11 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- IVL | c.975T>A p.H325Q | Missense Mutation (SNP) | VAF 97/467 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- JCAD | c.989T>A p.L330Q | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- KCNK7 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 49/217 reads (23%) | called by muse, mutect2, varscan2
- KLHL4 | c.4T>A p.S2T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- KRT1 | c.47dup p.F17Lfs*39 | Frame Shift Ins (INS) | VAF 36/166 reads (22%) | called by pindel, varscan2
- LGALS3 | c.750A>G p.I250M | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LOX | c.1184T>C p.V395A | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- LRFN5 | c.1422T>A p.N474K | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- LRRC52 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 259/567 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDGA2 | c.2956G>A p.G986R (on ENST00000399232 / NM_001113498.2; = p.G688R on NM_182830.4) | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MED23 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 64/351 reads (18%) | called by muse, mutect2, varscan2
- MPP4 | c.543G>T p.R181S | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MRPS5 | c.1042G>C p.G348R | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MUC16 | c.4265C>T p.P1422L | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NAIF1 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NDNF | c.1434T>A p.F478L | Missense Mutation (SNP) | VAF 97/258 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- NRP1 | c.943T>A p.W315R | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OAT | c.540del p.T181Rfs*49 | Frame Shift Del (DEL) | VAF 125/569 reads (22%) | called by mutect2, pindel, varscan2
- OR5B2 | c.404C>G p.T135R | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- OR6B2 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OTUD7A | c.1502A>T p.K501M (on ENST00000307050 / NM_001382637.1; = p.K494M on NM_130901.3) | Missense Mutation (SNP) | VAF 24/568 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2
- PEX5L | c.1433C>A p.T478K | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PGK2 | c.275A>T p.D92V | Missense Mutation (SNP) | VAF 131/504 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PLXNC1 | c.2389-1G>T p.X797_splice | Splice Site (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- PPP1R9B | c.1727T>A p.V576E | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIOK2 | c.1544C>A p.S515* | Nonsense Mutation (SNP) | VAF 22/566 reads (4%) | called by muse, mutect2
- RNF213 | c.1397A>G p.Y466C | Missense Mutation (SNP) | VAF 93/363 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RUNX1T1 | c.56G>T p.C19F | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- SECISBP2 | c.395C>A p.T132K | Missense Mutation (SNP) | VAF 105/421 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3BP5L | c.802A>T p.S268C | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO1A2 | c.1684C>A p.P562T | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLU7 | c.1459A>G p.M487V | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA31E1 | c.3448C>A p.L1150M | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.904); called by muse, mutect2
- SPIN3 | c.424G>T p.G142C | Missense Mutation (SNP) | VAF 74/132 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TAF8 | c.848G>T p.R283L | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- UBA3 | c.629C>A p.A210D | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- VGLL2 | c.928C>A p.L310I (on ENST00000326274 / NM_182645.3; = p.L136I on NM_153453.1) | Missense Mutation (SNP) | VAF 82/238 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- VIRMA | c.5192A>T p.N1731I | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDFY4 | c.1205G>C p.C402S | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ZFHX4 | c.345G>T p.E115D | Missense Mutation (SNP) | VAF 73/272 reads (27%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ZNF317 | c.1663del p.E555Rfs*23 | Frame Shift Del (DEL) | VAF 40/235 reads (17%) | called by mutect2, pindel, varscan2
- ZNF560 | c.1967A>C p.Y656S | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTRT2 | c.831G>C p.S277= | Silent (SNP) | VAF 65/213 reads (31%) | catalogued as COSV65759193; called by muse, mutect2, varscan2
- BNIP5 | c.1461C>T p.S487= | Silent (SNP) | VAF 35/208 reads (17%) | called by muse, varscan2
- BTBD7 | c.1725C>G p.L575= | Silent (SNP) | VAF 100/289 reads (35%) | called by muse, mutect2, varscan2
- CACNA1I | c.855G>T p.P285= | Silent (SNP) | VAF 96/484 reads (20%) | called by muse, mutect2, varscan2
- CCDC168 | c.2373G>C p.V791= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV70555200; called by muse, mutect2, varscan2
- CLMN | c.1146G>A p.Q382= | Silent (SNP) | VAF 149/404 reads (37%) | catalogued as rs1313240762; called by muse, mutect2, varscan2
- CNTNAP4 | c.1980G>T p.V660= | Silent (SNP) | VAF 60/223 reads (27%) | called by muse, mutect2, varscan2
- COL5A2 | c.2631A>G p.P877= | Silent (SNP) | VAF 144/535 reads (27%) | called by muse, mutect2, varscan2
- CWH43 | c.1215G>A p.L405= | Silent (SNP) | VAF 60/179 reads (34%) | called by muse, mutect2, varscan2
- DNAH5 | c.846G>A p.G282= | Silent (SNP) | VAF 58/278 reads (21%) | catalogued as rs748702437; called by muse, mutect2, varscan2
- ELFN1 | c.1938G>A p.V646= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- ENPP4 | c.1242A>T p.S414= | Silent (SNP) | VAF 96/334 reads (29%) | called by muse, mutect2, varscan2
- FMO5 | c.1539A>G p.T513= | Silent (SNP) | VAF 107/214 reads (50%) | called by muse, mutect2, varscan2
- FRMPD1 | c.3678C>A p.I1226= | Silent (SNP) | VAF 86/383 reads (22%) | called by muse, mutect2, varscan2
- GLT1D1 | c.676T>C p.L226= (on ENST00000442111 / NM_001366889.1; = p.L146= on NM_144669.3) | Silent (SNP) | VAF 85/306 reads (28%) | catalogued as rs780852432; called by muse, mutect2, varscan2
- HCN1 | c.1695C>T p.S565= | Silent (SNP) | VAF 99/387 reads (26%) | catalogued as rs553446512; ClinVar: likely benign; called by muse, mutect2, varscan2
- IFNA4 | c.36G>T p.L12= | Silent (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- IGHV4-34 | c.102C>T p.G34= | Silent (SNP) | VAF 136/401 reads (34%) | catalogued as rs1343694485; called by muse, mutect2, varscan2
- KCTD16 | c.1098C>T p.L366= | Silent (SNP) | VAF 150/619 reads (24%) | called by muse, mutect2, varscan2
- LAMA5 | c.9963G>A p.Q3321= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2
- LARGE1 | c.45G>T p.S15= | Silent (SNP) | VAF 132/666 reads (20%) | catalogued as COSV100505469; called by muse, mutect2, varscan2
- LRIT1 | c.876C>A p.G292= | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, varscan2
- MGAT4D | c.1110T>C p.Y370= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, varscan2
- NAB1 | c.570G>T p.A190= | Silent (SNP) | VAF 60/204 reads (29%) | called by muse, mutect2, varscan2
- OR10Z1 | c.882T>C p.N294= | Silent (SNP) | VAF 63/295 reads (21%) | catalogued as COSV100778941; called by muse, mutect2, varscan2
- OR2G2 | c.771C>A p.T257= | Silent (SNP) | VAF 122/266 reads (46%) | called by muse, mutect2, varscan2
- OR2L2 | c.837C>A p.I279= | Silent (SNP) | VAF 60/375 reads (16%) | called by muse, mutect2, varscan2
- OR51L1 | c.642C>T p.I214= | Silent (SNP) | VAF 32/157 reads (20%) | called by muse, mutect2, varscan2
- OR6B2 | c.570G>T p.T190= | Silent (SNP) | VAF 78/276 reads (28%) | catalogued as rs766500820, COSV53155563; called by muse, mutect2, varscan2
- PLCH1 | c.1563C>T p.A521= (on ENST00000340059 / NM_001130960.2; = p.A533= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 58/120 reads (48%) | called by muse, mutect2, varscan2
- PLP1 | c.273C>T p.F91= | Silent (SNP) | VAF 109/168 reads (65%) | called by muse, mutect2, varscan2
- PPP1R9B | c.387G>T p.A129= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- RRP15 | c.24A>T p.S8= | Silent (SNP) | VAF 38/184 reads (21%) | called by muse, mutect2, varscan2
- RYR2 | c.3153C>T p.R1051= | Silent (SNP) | VAF 76/155 reads (49%) | catalogued as rs397516524; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely benign; called by muse, mutect2, varscan2
- SCN2A | c.1824A>G p.R608= | Silent (SNP) | VAF 79/310 reads (25%) | called by muse, mutect2, varscan2
- SLC24A4 | c.1209G>A p.E403= | Silent (SNP) | VAF 111/375 reads (30%) | called by muse, mutect2
- SLC45A2 | c.525C>T p.D175= | Silent (SNP) | VAF 101/386 reads (26%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.312C>A p.A104= | Silent (SNP) | VAF 70/224 reads (31%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.576G>T p.L192= | Silent (SNP) | VAF 62/220 reads (28%) | called by muse, mutect2, varscan2
- TMEM214 | c.1659C>T p.H553= | Silent (SNP) | VAF 41/105 reads (39%) | called by muse, mutect2, varscan2
- TTN | c.5628C>A p.L1876= (on ENST00000591111; = p.L1830= on NM_003319.4) | Silent (SNP) | VAF 55/401 reads (14%) | called by muse, mutect2, varscan2
- TTN | c.2667T>G p.T889= (on ENST00000591111; = p.T843= on NM_003319.4) | Silent (SNP) | VAF 27/542 reads (5%) | called by muse, mutect2
- WNT9A | c.933T>G p.R311= | Silent (SNP) | VAF 84/445 reads (19%) | called by muse, mutect2, varscan2
- WRN | c.3525A>T p.P1175= | Silent (SNP) | VAF 111/391 reads (28%) | called by muse, mutect2, varscan2
- ZNF726 | c.348T>C p.G116= | Silent (SNP) | VAF 55/147 reads (37%) | called by muse, mutect2, varscan2
- ADH5P5 | chr5:23980002 del C | 5'Flank (DEL) | VAF 29/116 reads (25%) | called by mutect2, pindel, varscan2
- ADRB3 | c.*16A>G | 3'UTR (SNP) | VAF 62/225 reads (28%) | called by muse, mutect2, varscan2
- BCAS3 | c.2075-4698G>A | Intron (SNP) | VAF 148/634 reads (23%) | called by muse, mutect2, varscan2
- CCR7 | c.-28T>A | 5'UTR (SNP) | VAF 63/261 reads (24%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56812131 del G | 3'Flank (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel, varscan2
- CNTN4 | c.1358+1576A>G | Intron (SNP) | VAF 49/144 reads (34%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*4666T>C | 3'UTR (SNP) | VAF 34/135 reads (25%) | called by muse, mutect2, varscan2
- CXADRP2 | n.387G>T | RNA (SNP) | VAF 4/27 reads (15%) | called by mutect2, varscan2
- EZH2 | c.1225+34C>G | Intron (SNP) | VAF 28/83 reads (34%) | called by muse, varscan2
- IGHM | c.1300+25C>A | Intron (SNP) | VAF 167/421 reads (40%) | called by muse, mutect2, varscan2
- ITGA2B | c.*20C>T | 3'UTR (SNP) | VAF 73/275 reads (27%) | called by muse, mutect2, varscan2
- LMO4 | chr1:87348796 T>C | 3'Flank (SNP) | VAF 50/108 reads (46%) | catalogued as rs1459090063; called by muse, mutect2, varscan2
- LYST | c.8359-16A>G | Intron (SNP) | VAF 18/77 reads (23%) | catalogued as rs767579224; called by muse, mutect2, varscan2
- MS4A6A | c.282+21G>T | Intron (SNP) | VAF 156/487 reads (32%) | catalogued as rs749633289; called by muse, mutect2, varscan2
- MSR1 | c.1034-552del | Intron (DEL) | VAF 28/113 reads (25%) | called by mutect2, pindel, varscan2
- NBEA | c.7618-351C>A | Intron (SNP) | VAF 44/210 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-68125C>T | Intron (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- RABGAP1L | c.2340+65557T>C | Intron (SNP) | VAF 70/432 reads (16%) | called by muse, mutect2, varscan2
- RBM25 | c.1468-70C>T | Intron (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2
- RPH3A | c.611-28C>G | Intron (SNP) | VAF 36/166 reads (22%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23891A>T | Intron (SNP) | VAF 57/189 reads (30%) | called by muse, mutect2, varscan2
- SNORD116-20 | n.7A>T | RNA (SNP) | VAF 89/339 reads (26%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3001A>T | Intron (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- STARD13 | c.170-18373G>T | Intron (SNP) | VAF 63/284 reads (22%) | called by muse, mutect2, varscan2
- TMEM191C | c.421-39G>A | Intron (SNP) | VAF 13/99 reads (13%) | catalogued as rs1226313384; called by muse, mutect2, varscan2
- TP53BP1 | c.2821+42G>A | Intron (SNP) | VAF 41/126 reads (33%) | catalogued as rs1237900132; called by muse, mutect2, varscan2
- TRPM3 | c.184-256699G>T | Intron (SNP) | VAF 61/184 reads (33%) | catalogued as COSV100623876; called by muse, mutect2, varscan2
- UFM1 | c.2+18G>T | Intron (SNP) | VAF 95/357 reads (27%) | catalogued as rs371532681; called by muse, mutect2, varscan2
- ZNF471 | c.*1G>T | 3'UTR (SNP) | VAF 8/28 reads (29%) | catalogued as COSV100340272; called by muse, varscan2
